Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A1EI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A1EI-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8/10/3

Site Code: Liver C22.0

1/19/11 *fw*

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

... A1 A2 A3 B1 B2 B3 B4 B5
Right lobe liver (765.0 grams, 16.0 x 13.0 x 11.0 cm) and
separately submitted gallbladder (8.0 x 4.0 x 1.0 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 2 (of 4) hepatocellular
carcinoma forming a mass (1.8 x 1.5 x 1.0 cm) located 0.6 cm
from the cauterized margin. The surrounding liver parenchyma
shows chronic hepatitis consistent with clinical hepatitis B,
mildly active (grade 2 of 4) with cirrhosis (stage 4/4). ✓

Gallbladder, cholecystectomy: Benign gallbladder mucosa with
cholelithiasis containing multiple (2) cholesterol stones (0.3
cm in greatest dimension, each).

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver, right lobe, resection: Grade 2 (of 4) hepatocellular
carcinoma. History of hepatitis B. Hold over to categorize
surrounding liver.

Diagnosis Discrepancy		K
Primary Tumor Site Discrepancy		K
HIPAA Discrepancy		K
Prior Malignancy History		K
Dual/Synchronous Primary Tumor		K

[page 2 of 4]
Patient key:

Patient Key:

Surgical date: ...

TISSUE DESCRIPTION:

... A1 A2 A3 B1 B2 B3 B4 B5
Right lobe liver (765.0 grams, 16.0 x 13.0 x 11.0 cm) and
separately submitted gallbladder (8.0 x 4.0 x 1.0 cm).

DIAGNOSIS:

Liver, right lobe, resection: Grade 2 (of 4) hepatocellular carcinoma forming a mass (1.8 x 1.5 x 1.0 cm) located 0.6 cm from the cauterized margin. The surrounding liver parenchyma shows chronic hepatitis consistent with clinical hepatitis B, mildly active (grade 2 of 4) with cirrhosis (stage 4/4).

Gallbladder, cholecystectomy: Benign gallbladder mucosa with cholelithiasis containing multiple (2) cholesterol stones (0.3 cm in greatest dimension, each).

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver, right lobe, resection: Grade 2 (of 4) hepatocellular carcinoma. History of hepatitis B. Hold over to categorize surrounding liver.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: ResectionPatient name: *(to be de-identified)*

Surgical pathology number:

MACROSCOPIC**Specimen Type**

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): right lobe
☐ Multiple (specify location): _____

Tumor SizeGreatest dimension: 1.8 cm*Additional dimensions: 1.5 x 1.0 cm☐ Cannot be determined (see Comment)**MICROSCOPIC****Histologic Type**

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☒ GI: Well differentiated
☒ GII: Moderately differentiated
☐ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☒ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☐ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis
Specify: Number examined: ____
Number involved: ____

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis
*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☒ Cannot be assessed
☒ Uninvolved by invasive carcinoma 6.0
Distance of invasive carcinoma from closest margin: ____ mm
Specify margin: _____
☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☒ Cannot be assessed
☐ Uninvolved by invasive carcinoma
* ☐ Carcinoma in situ absent
* ☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

- Specify margin: _____
☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☐ None identified
* ☐ Hepatocellular dysplasia
* ☒ Ductal dysplasia
* ☒ Cirrhosis/fibrosis
* ☐ Iron overload
* ☒ Hepatitis (specify type): chronic hepatitis B
* ☐ Other (specify): _____

Source: NCI Genomic Data Commons file 3ab536fd-0a53-47df-a075-6df788b7f881 (TCGA-DD-A1EI.C253EB16-129F-4442-8C88-8A132E610E8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).